Somatic mutation profile of tumor specimen TCGA-69-8254-01A (aliquot TCGA-69-8254-01A-11D-2284-08) from TCGA case TCGA-69-8254, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; Age at diagnosis: 85.2 years (31,134 days).
Specimen TCGA-69-8254-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85778361-3032-4076-9fd5-5cdee32285bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-69-8254-10A (Blood Derived Normal), aliquot TCGA-69-8254-10A-01D-2284-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c35a4b3-744d-45a4-a95a-6369e88e9d98

The open-access MAF lists 79 somatic variants for this specimen: 66 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 12, Nonsense Mutation 6, Frame Shift Del 3, Splice Site 3, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 4/29 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ACSM2A | c.432C>G p.D144E (on ENST00000219054; = p.D65E on NM_001308169.2) | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99525282; called by muse, mutect2, varscan2
- ARHGAP19 | c.1331A>T p.N444I | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as COSV100363201; called by muse, mutect2, varscan2
- ARHGEF12 | c.1577T>C p.I526T | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100754938; called by muse, mutect2, varscan2
- ATRX | c.1297A>G p.K433E | Missense Mutation (SNP) | VAF 79/167 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs898727479, COSV100970814; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCL9L | c.1015G>T p.V339L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV99419332; called by muse, varscan2
- C8orf76 | c.297G>T p.Q99H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV99415037; called by muse, mutect2, varscan2
- CCNI | c.481A>G p.T161A | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs1418019804, COSV99423468; called by muse, mutect2
- CCSER1 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs549014692, COSV100392068; called by muse, varscan2
- CMKLR1 | c.380T>A p.V127D (on ENST00000312143 / NM_001142344.2; = p.V125D on NM_004072.3) | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100379441; called by muse, mutect2, varscan2
- COL22A1 | c.529G>A p.V177M | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs759460539, COSV57339725; called by muse, mutect2, varscan2
- CRABP2 | c.281T>C p.M94T | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as COSV100957561; called by muse, mutect2, varscan2
- CSMD3 | c.9964A>G p.I3322V (on ENST00000297405 / NM_001363185.1; = p.I3153V on NM_052900.3) | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99826549, COSV99835214; called by muse, mutect2, varscan2
- CYP20A1 | c.924A>T p.Q308H | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100619056; called by muse, mutect2, varscan2
- DMXL1 | c.605G>T p.W202L | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.177); catalogued as COSV100223426, COSV100224010; called by muse, mutect2, varscan2
- FGR | c.278A>C p.E93A | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100925828; called by muse, mutect2, varscan2
- FMO2 | c.560T>C p.I187T | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV99269146; called by muse, mutect2
- FOXI1 | c.93C>A p.Y31* | Nonsense Mutation (SNP) | VAF 4/46 reads (9%) | catalogued as COSV100089363; called by muse, mutect2
- GABRA4 | c.719C>T p.T240M | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1324245904, COSV51921667; called by muse, mutect2, varscan2
- GRIN2A | c.1967A>T p.E656V | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100409900; called by muse, mutect2, varscan2
- GTF2F1 | c.1375G>A p.V459M | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs560145579, COSV55533098; called by muse, mutect2, varscan2
- HAS1 | c.846C>A p.S282R | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99708420; called by muse, mutect2, varscan2
- HLA-DMA | c.553C>T p.Q185* | Nonsense Mutation (SNP) | VAF 14/72 reads (19%) | catalogued as COSV100877672; called by muse, mutect2, varscan2
- IPO13 | c.2638A>G p.S880G | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.075); catalogued as COSV99664481; called by muse, mutect2, varscan2
- KCNC2 | c.157A>T p.K53* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as COSV100128873; called by muse, mutect2, varscan2
- KIR2DL1 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 86/444 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); catalogued as COSV99383117; called by muse, mutect2, varscan2
- KLKB1 | c.461C>T p.T154M | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.397); catalogued as rs373868869, COSV52999312; called by muse, mutect2, varscan2
- KRTAP5-11 | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.024); catalogued as COSV100651811; called by muse, mutect2, varscan2
- KRTAP8-1 | c.142G>A p.G48S | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.987); catalogued as rs752400975, COSV61598328; called by muse, mutect2, varscan2
- LMAN1L | c.718+2T>A p.X240_splice | Splice Site (SNP) | VAF 25/126 reads (20%) | catalogued as COSV100547713; called by muse, mutect2, varscan2
- LRRC7 | c.3923G>A p.W1308* (on ENST00000651989 / NM_001370785.2; = p.W1275* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 16/129 reads (12%) | catalogued as COSV99227128; called by muse, mutect2, varscan2
- MTF1 | c.2179G>T p.D727Y | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); catalogued as COSV100888639; called by muse, mutect2, varscan2
- NCOA5 | c.359T>C p.M120T | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.66); PolyPhen benign (0.006); catalogued as rs750109939, COSV99275621; called by muse, mutect2, varscan2
- OPA3 | c.437A>T p.Q146L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99619958; called by muse, mutect2, varscan2
- OPRK1 | c.944G>T p.C315F | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV99654096; called by muse, mutect2, varscan2
- OR10X1 | c.891C>A p.F297L | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT tolerated (1); PolyPhen probably damaging (0.98); catalogued as COSV100936663; called by muse, mutect2, varscan2
- OR2H1 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs777238942, COSV101009803; called by muse, mutect2, varscan2
- PDE11A | c.29T>G p.F10C | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100628886; called by muse, mutect2, varscan2
- PDGFRB | c.2132C>A p.P711H | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.626); catalogued as COSV99940637; called by muse, mutect2, varscan2
- PHRF1 | c.4870G>A p.V1624M (on ENST00000264555 / NM_001286581.2; = p.V1623M on NM_020901.4) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1315887843, COSV52757566; called by muse, mutect2, varscan2
- PKD1L2 | c.1415T>C p.I472T | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV100449916; called by muse, mutect2, varscan2
- RASSF1 | c.484G>T p.G162C (on ENST00000357043 / NM_170714.2; = p.G158C on NM_007182.5) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99222743; called by muse, mutect2, varscan2
- RBM10 | c.2430+2T>A p.X810_splice | Splice Site (SNP) | VAF 7/19 reads (37%) | catalogued as COSV100237850; called by muse, mutect2, varscan2
- RCC2 | c.1558C>T p.R520* | Nonsense Mutation (SNP) | VAF 18/92 reads (20%) | catalogued as COSV100965161; called by muse, mutect2, varscan2
- RPE65 | c.1013A>G p.Y338C | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.989); catalogued as COSV99253943; called by muse, mutect2, varscan2
- RRP1 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1018295414, COSV101513873; called by muse, mutect2
- SLC44A5 | c.1987A>C p.I663L | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV100902060; called by muse, mutect2, varscan2
- SORL1 | c.5611G>T p.G1871C | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52759745, COSV99494014; called by muse, mutect2, varscan2
- SPATA9 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 15/77 reads (19%) | catalogued as COSV99174155; called by muse, mutect2, varscan2
- SUMO3 | c.162G>A p.M54I | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100254426; called by muse, mutect2, varscan2
- TCP11L2 | c.575C>G p.P192R | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100135364; called by muse, mutect2, varscan2
- TFRC | c.2051A>T p.H684L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV100786496; called by muse, mutect2
- UEVLD | c.716-2A>G p.X239_splice | Splice Site (SNP) | VAF 11/57 reads (19%) | catalogued as COSV57873881; called by muse, mutect2, varscan2
- UST | c.693G>T p.E231D | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.041); catalogued as COSV66550051, COSV99054932; called by muse, mutect2, varscan2
- WDR73 | c.917C>G p.T306R | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.79); catalogued as COSV100822085; called by muse, mutect2
- WDR90 | c.1504C>T p.H502Y | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV99553473; called by muse, mutect2
- ZCWPW1 | c.185A>G p.K62R | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.393); catalogued as COSV100228261; called by muse, mutect2, varscan2
- ZEB1 | c.1055A>T p.D352V | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100314466; called by muse, mutect2, varscan2
- ZFP36L1 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100322705; called by muse, mutect2, varscan2
- ZNF559-ZNF177 | c.672G>C p.K224N | Missense Mutation (SNP) | VAF 6/172 reads (3%) | SIFT tolerated (0.5); PolyPhen benign (0.381); catalogued as COSV100606152; called by muse, mutect2
- ZNF808 | c.2444C>T p.A815V | Missense Mutation (SNP) | VAF 52/235 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as rs374120983; called by muse, mutect2, varscan2
- ZSCAN5B | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs750881936, COSV62838346; called by muse, mutect2, varscan2
- APC | c.6407_6409del p.L2136_S2137delinsP | In Frame Del (DEL) | VAF 13/103 reads (13%) | called by mutect2, pindel, varscan2
- DHX34 | c.231_232del p.K78Gfs*54 | Frame Shift Del (DEL) | VAF 22/135 reads (16%) | called by mutect2, pindel, varscan2
- KLK13 | c.93del p.T32Pfs*23 | Frame Shift Del (DEL) | VAF 16/109 reads (15%) | called by mutect2, pindel, varscan2
- THRAP3 | c.2270_2271del p.T757Rfs*5 | Frame Shift Del (DEL) | VAF 15/91 reads (16%) | called by mutect2, pindel, varscan2
- AMIGO2 | c.393G>A p.T131= | Silent (SNP) | VAF 26/128 reads (20%) | catalogued as rs1264592058, COSV99873615; called by muse, mutect2, varscan2
- CCDC74A | c.516C>T p.F172= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV99723737, COSV99723903; called by mutect2, varscan2
- CCDC74B | c.516C>T p.F172= | Silent (SNP) | VAF 6/46 reads (13%) | called by mutect2, varscan2
- CD82 | c.204C>T p.L68= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as COSV99907586; called by muse, mutect2, varscan2
- OR2H1 | c.282A>C p.G94= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as rs760090748, COSV65811771; called by muse, mutect2, varscan2
- PTGFRN | c.996G>A p.A332= | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as rs745764390, COSV101277316; called by muse, mutect2, varscan2
- SCAMP2 | c.399C>T p.F133= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as COSV99173959; called by muse, mutect2, varscan2
- SLC4A2 | c.342G>T p.P114= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV100055406; called by muse, mutect2, varscan2
- SLIT3 | c.4500G>A p.Q1500= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV100267670; called by muse, mutect2, varscan2
- STC2 | c.237G>T p.R79= | Silent (SNP) | VAF 68/344 reads (20%) | catalogued as rs765762557, COSV54180079, COSV99438402; called by muse, mutect2, varscan2
- SUSD5 | c.402G>A p.K134= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV100535138; called by muse, mutect2, varscan2
- ZNF548 | c.1440C>T p.S480= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as rs1414270177, COSV100278155; called by muse, mutect2, varscan2
- NIBAN3 | c.1844-1504G>A | Intron (SNP) | VAF 7/27 reads (26%) | catalogued as rs1262402506, COSV99395070; called by muse, mutect2, varscan2
